Somatic mutation profile of tumor specimen 0DMUZ6 from CCDI case PBCAHY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.8 years (3,938 days).
Specimen 0DMUZ6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0471bb55-f610-4650-ab3c-df2768756abf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMUX8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c8e9ee2-0916-438d-bbb3-058aa9da6dbe

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Splice Region 1, RNA 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.6849+1G>A p.X2283_splice | Splice Site (SNP) | VAF 86/299 reads (29%) | catalogued as COSV64871015, COSV64880078; called by muse, mutect2, varscan2
- OBSCN | c.6603C>T p.D2201= | Splice Region (SNP) | VAF 76/514 reads (15%) | catalogued as rs1056756857; called by muse, mutect2, varscan2
- TIPARP | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 24/537 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1358581953, COSV55813452; called by muse, mutect2
- C8A | c.1416C>G p.S472R | Missense Mutation (SNP) | VAF 44/830 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.124); called by muse, mutect2
- GALNT15 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 186/656 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- GYS1 | c.782T>C p.I261T | Missense Mutation (SNP) | VAF 175/659 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- SNCAIP | c.2639A>T p.N880I | Missense Mutation (SNP) | VAF 40/410 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- LAMA5 | c.7150C>T p.L2384= | Silent (SNP) | VAF 71/643 reads (11%) | called by muse, mutect2, varscan2
- OXR1 | c.985A>C p.R329= (on ENST00000442977 / NM_001198532.1; = p.R328= on NM_018002.3) | Silent (SNP) | VAF 162/538 reads (30%) | called by muse, mutect2, varscan2
- SERPINA4 | c.252G>A p.A84= | Silent (SNP) | VAF 88/744 reads (12%) | catalogued as rs767013382, COSV54070381; called by muse, mutect2, varscan2
- C8orf87 | n.1A>C | RNA (SNP) | VAF 20/141 reads (14%) | called by muse, mutect2, varscan2
- NET1 | c.*19A>G | 3'UTR (SNP) | VAF 73/226 reads (32%) | called by muse, mutect2, varscan2
